TCGA case TCGA-VQ-A8PZ — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Stomach; Tissue source site: Barretos Cancer Hospital. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/91c94a0d-f088-40e6-a4b1-d2a72ad35077

Demographics
Sex at birth: female; Race: white; Country of residence at enrollment: Brazil; Age at index: 56 years; Vital status: Alive.

Diagnoses (1)
1. Signet ring cell carcinoma: ICD-O-3 morphology code: 8490/3; ICD-10 code: C16.3; Tissue or organ of origin: Gastric antrum; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 56.8 years (20,735 days); Year of diagnosis: 2008; AJCC staging edition: 6th; AJCC pathologic T: T3; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage II; Tumor grade: G3; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 2,233 days (6.1 years).
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 0; Lymph nodes tested: 68.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Fluorouracil; Days to treatment start: 121 days; Days to treatment end: 234 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Radiation, External Beam; Days to treatment start: 230 days; Days to treatment end: 269 days; Treatment dose: 4,500 cGy; Treatment outcome: Complete Response; Number of fractions: 25; Treatment anatomic sites: Primary Tumor Field.

Follow-up (3 entries)
- Days to follow up: 1,800 days (4.9 years); Disease response: Tumor Free.
- Days to follow up: 1,982 days (5.4 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: day 2,233.

Family history
- Relative with cancer history: no.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VQ-A8PZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Initial weight: 110 mg.
  Slide TCGA-VQ-A8PZ-01A-01-TS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 65; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 5; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VQ-A8PZ-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VQ-A8PZ-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Stomach Adenocarcinoma, Signet Ring Type; History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: Fundus/Body; Lymph nodes examined: Yes; Tumor sample procurement country: Sao Paulo; Cancer procurement city: Barretos; History reflux disease indicator: No; Antireflux treatment: No; History barretts esophageal indicator: No; History hpylori infection indicator: No; Treatment outcome first course: Complete Remission/Response; New tumor event diagnosis indicator: No.
- Follow-up form 1: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Treatment outcome at TCGA followup: Complete Remission/Response.

GDC annotations on this case (curator notes; quoted as recorded):
- Genotype mismatch (a sample-identity caveat) on analyte TCGA-VQ-A8PZ-01A-11R: The RNA associated with UUID D67ED0A1-3738-4756-B8F2-5DB1902488D6 was involved in an extraction error that resulted in a genotype mismatch with its corresponding tumor DNA. This only affected the tumor RNA as DNA from the tumor and normal sample have the correct matching genotype.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-VQ-A8PZ-01A-11R-A414-31: The RNA associated with UUID 47F4B7A3-A85D-4500-AD6A-50AA8DDB0344 was involved in an extraction error that resulted in a genotype mismatch with its corresponding tumor DNA. This only affected the tumor RNA as DNA from the tumor and normal sample have the correct matching genotype.
- Genotype mismatch (a sample-identity caveat) on aliquot TCGA-VQ-A8PZ-01A-11R-A415-13: The RNA associated with UUID 52D0DBFF-82B3-4AED-8B6C-DA964D492253 was involved in an extraction error that resulted in a genotype mismatch with its corresponding tumor DNA. This only affected the tumor RNA as DNA from the tumor and normal sample have the correct matching genotype.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 2,233 days; disease-specific survival: no event (censored), 2,233 days; disease-free interval: no event (censored), 2,233 days; progression-free interval: no event (censored), 2,233 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VQ-A8PZ-01A-11D-A40Z-01): tumor purity 0.34, ploidy 1.79, whole-genome doublings 0.
